Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A94R, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A94R-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD O-3
Adenocarcinoma, intestinal
814413
Site: Gastric antrum C16.3
JW 3/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

"1-Subtotal gastrectomy + omentum:

Moderately differentiated gastric adenocarcinoma, intestinal pattern of Lauren (size: 5.0cm), infiltrating to perigastric adipose tissue.

Present foci of vascular invasion.

Perineural invasion not observed.

Surgical margins uninvolved by neoplasia.

Metastasis in 6 perigastric lymph nodes, with extranodal invasion (6/32).

2-Lymph node from chain 8A:

One lymph node uninvolved by neoplasia (0/1).

3-Lymph nodes from chain 8P:

Five lymph nodes uninvolved by neoplasia (0/5).

4-Lymph nodes from lesser curvature and celiac trunk:

Seventeen lymph nodes uninvolved by neoplasia (0/17)."

Metastasis Discrepancy		☒
Quasi-synchronous Primary/Noted		☒
Case Is Ineligible		☒

Date Rejected: 4/18/13

Source: NCI Genomic Data Commons file 70b895d2-d635-4351-a346-f69b4fb62199 (TCGA-VQ-A94R.81C82A47-2DD7-4620-AD0E-E4105EC62322.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).